Somatic mutation profile of tumor specimen TCGA-L5-A88T-01A (aliquot TCGA-L5-A88T-01A-11D-A351-09) from TCGA case TCGA-L5-A88T, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 86.2 years (31,480 days).
Specimen TCGA-L5-A88T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51008696-bb45-4271-8170-c1cf63fa6b96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88T-11A (Solid Tissue Normal), aliquot TCGA-L5-A88T-11A-11D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed175f3e-6db3-489e-85df-86443c20f320

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 4, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNMD | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs370148794; called by muse, mutect2, varscan2
- HCN1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as rs541911994, COSV57491575; called by muse, mutect2, varscan2
- KCTD7 | c.709C>T p.R237W (on ENST00000275532; = p.T250M on NM_153033.5) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs760837610, COSV51876936; ClinVar: uncertain significance; called by mutect2, varscan2
- KLF12 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs748773890; called by mutect2, varscan2
- NOTCH1 | c.1650C>G p.Y550* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV104374504, COSV53099012, COSV53109473; called by muse, mutect2, varscan2
- PDE4D | c.652G>A p.G218R (on ENST00000340635 / NM_001104631.2; = p.G82R on NM_006203.4) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs763492345, COSV58955720; called by muse, mutect2
- PHF2 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs867990076; called by muse, mutect2
- POTEE | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs549330020, COSV100388529; called by muse, mutect2, varscan2
- RIMS1 | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776226425, COSV53463446; called by muse, mutect2
- SLC39A8 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as COSV63222242; called by muse, mutect2
- TASOR2 | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); catalogued as rs1365266627; called by muse, mutect2
- THSD1 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs142793367; called by muse, mutect2, varscan2
- TNKS2 | c.3321C>A p.F1107L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65415982; called by muse, mutect2
- UBR1 | c.4987G>A p.G1663R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336388891; called by muse, mutect2
- USP6 | c.2954G>A p.R985K | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.007); catalogued as rs751186363; called by muse, mutect2
- ZNF516 | c.1143G>T p.Q381H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1465219126; called by muse, mutect2
- ZNF835 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV73379294; called by muse, mutect2
- ZSCAN1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs148253808; called by muse, mutect2, varscan2
- ACTR3 | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP17A | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); called by muse, mutect2
- ANKRD30A | c.3257A>C p.N1086T (on ENST00000611781; = p.N1030T on NM_052997.2) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- CD160 | c.514G>C p.V172L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- CLIC5 | c.728A>G p.D243G (on ENST00000185206 / NM_001370649.1; = p.D84G on NM_016929.5) | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSMD3 | c.5146G>A p.D1716N (on ENST00000297405 / NM_001363185.1; = p.D1612N on NM_052900.3) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- DLG4 | c.506G>A p.G169D (on ENST00000399506 / NM_001321075.3; = p.G212D on NM_001365.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.336); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2291A>G p.Q764R | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- ETV2 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- FAT1 | c.8962A>T p.K2988* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- MYH14 | c.4353G>A p.M1451I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MYSM1 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARD3 | c.137dup p.Q47Tfs*16 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- PARD3B | c.2871C>G p.N957K (on ENST00000406610 / NM_001302769.2; = p.N888K on NM_057177.7) | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- RIMS2 | c.2821C>T p.R941* (on ENST00000666250 / NM_001348490.2; = p.R749* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2
- SLC7A14 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- STAB2 | c.4279T>G p.C1427G | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TDRD5 | c.2210A>C p.D737A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TFAP2C | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/394 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- UGT2B15 | c.1342A>G p.R448G | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- AMBP | c.72G>A p.T24= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs750913733, COSV54324996; called by muse, mutect2, varscan2
- CNMD | c.429G>A p.E143= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- DERA | c.60G>C p.V20= | Silent (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- ERICH3 | c.2922T>C p.I974= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- HDAC9 | c.3061A>C p.R1021= (on ENST00000441542 / NM_178425.3; = p.R1018= on NM_178423.3) | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MICU1 | c.681C>T p.F227= (on ENST00000361114 / NM_001195518.2; = p.F233= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PLA2G4C | c.1254C>T p.F418= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs750061156, COSV62784527, COSV62787647; called by muse, mutect2, varscan2
- TMPRSS15 | c.1056C>A p.G352= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV99519350; called by muse, mutect2
- TRIM75P | c.1224G>A p.V408= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- TTN | c.77388T>C p.G25796= (on ENST00000591111; = p.G18372= on NM_003319.4) | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- TTN | c.3774T>A p.I1258= (on ENST00000591111; = p.I1212= on NM_003319.4) | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, varscan2
- VNN1 | c.231T>G p.T77= | Silent (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
